Somatic mutation profile of tumor specimen TCGA-CS-6670-01A (aliquot TCGA-CS-6670-01A-11D-1893-08) from TCGA case TCGA-CS-6670, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 44.0 years (16,066 days).
Specimen TCGA-CS-6670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0b9994a-87e4-4009-924b-bfd13222c654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6670-10A (Blood Derived Normal), aliquot TCGA-CS-6670-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a4845f-b607-486b-8a84-a3080f1eab4a

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATG2A | c.2982A>G p.R994= | Splice Region (SNP) | VAF 14/143 reads (10%) | catalogued as COSV101034347; called by muse, mutect2, varscan2
- CECR2 | c.1684C>T p.R562W (on ENST00000342247 / NM_001290047.2; = p.R379W on NM_001290046.1) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs768986689, COSV52840831; called by muse, mutect2, varscan2
- COBL | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as rs778387480, COSV99472638; called by muse, mutect2, varscan2
- CTNNA3 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs779423519, COSV57717865, COSV57720911; called by muse, mutect2, varscan2
- CUL4B | c.611-2A>G p.X204_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100340538; called by muse, mutect2, varscan2
- DBT | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs773026845, COSV64495910; called by muse, mutect2, varscan2
- DLGAP2 | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1420223047, COSV101421906; called by muse, mutect2, varscan2
- GPR85 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.664); catalogued as rs1289985298, COSV99775197; called by muse, mutect2, varscan2
- HROB | c.1523G>A p.S508N | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV99809251; called by muse, mutect2, varscan2
- ICE1 | c.5927C>G p.S1976* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99664784; called by muse, mutect2, varscan2
- KRT5 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as CM162865, COSV99358024; called by muse, mutect2, varscan2
- LATS2 | c.3013G>A p.V1005I | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs780614508, COSV66873586; called by muse, mutect2, varscan2
- MATK | c.563A>G p.N188S (on ENST00000310132 / NM_139355.3; = p.N189S on NM_002378.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100036096; called by muse, mutect2
- NPY1R | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as rs1416290233, COSV56714595, COSV99648760; called by muse, mutect2, varscan2
- OR5H14 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV101454171; called by muse, mutect2, varscan2
- OR5K4 | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100721349; called by muse, mutect2, varscan2
- PCDHGA2 | c.2255C>G p.T752S | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); catalogued as COSV99538390; called by muse, mutect2, varscan2
- PTPN4 | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.859); catalogued as rs753221021, COSV55301223; called by muse, mutect2, varscan2
- SCN2B | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs140034265; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SHC4 | c.1172T>G p.M391R | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100194594; called by muse, mutect2, varscan2
- SLC4A2 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.158); catalogued as COSV100055368, COSV59657383; called by muse, mutect2, varscan2
- SPATA31E1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.488); catalogued as COSV100350455; called by muse, mutect2, varscan2
- SPATA9 | c.487A>G p.N163D | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99174153; called by muse, mutect2, varscan2
- UGT1A7 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100692853; called by muse, mutect2, varscan2
- URB2 | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs1558166392, COSV99271137; called by muse, mutect2, varscan2
- PTPRZ1 | c.4915dup p.I1639Nfs*42 | Frame Shift Ins (INS) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.6657T>C p.S2219= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100518578; called by muse, varscan2
- FBXO38 | c.1680T>C p.N560= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99693446; called by muse, mutect2
- IGF2R | c.5298T>C p.C1766= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV100807373; called by muse, mutect2, varscan2
- PTPN13 | c.1501T>C p.L501= | Silent (SNP) | VAF 21/156 reads (13%) | catalogued as rs750891556, COSV100364763; called by muse, mutect2, varscan2
- TTN | c.19917G>A p.P6639= (on ENST00000591111; = p.P5712= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs367929968; ClinVar: likely benign; called by muse, mutect2, varscan2
- ULK4 | c.2274T>C p.Y758= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs377580198; called by muse, mutect2, varscan2
- WDR49 | c.1281T>C p.S427= (on ENST00000308378 / NM_001366158.1; = p.S768= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100392780; called by muse, mutect2, varscan2
